Somatic mutation profile of tumor specimen TARGET-30-PAUMMZ-01A (aliquot TARGET-30-PAUMMZ-01A-01D) from TARGET case TARGET-30-PAUMMZ, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.1 years (1,507 days).
Specimen TARGET-30-PAUMMZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e6e51fb-216c-4af0-8878-ec8d688a9511.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUMMZ-10A (Blood Derived Normal), aliquot TARGET-30-PAUMMZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ff27a7e-c672-4dd4-928d-0ee22fd7f9ba

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MXRA5 | c.663C>A p.C221* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- TPTE | c.57C>T p.P19= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as rs563344234; called by muse, mutect2, varscan2
- AR | c.*4949G>C | 3'UTR (SNP) | VAF 31/73 reads (42%) | catalogued as COSV65959877; called by muse, mutect2, varscan2
- FGFR1 | c.*1091G>T | 3'UTR (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
